Somatic mutation profile of tumor specimen TARGET-30-PASKPC-01A (aliquot TARGET-30-PASKPC-01A-01D) from TARGET case TARGET-30-PASKPC, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Unknown primary site; Age at diagnosis: 2.6 years (964 days).
Specimen TARGET-30-PASKPC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0db67a05-c8b0-4db3-a0cb-496ff4bb164a.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASKPC-10A (Blood Derived Normal), aliquot TARGET-30-PASKPC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51f7d78c-7a22-4f3d-9b9b-d5ff73affd12

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, Silent 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.6834G>C p.K2278N | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- ETV6 | c.770G>T p.S257I | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ATP1A2 | c.2151C>T p.N717= | Silent (SNP) | VAF 25/105 reads (24%) | catalogued as rs140707454, CM078259, COSV63402347, COSV63404669; called by muse, mutect2, varscan2
- USP6 | c.-1311G>T | 5'UTR (SNP) | VAF 9/81 reads (11%) | called by muse, mutect2, varscan2
